Somatic mutation profile of tumor specimen TCGA-B6-A0RG-01A (aliquot TCGA-B6-A0RG-01A-11W-A071-09) from TCGA case TCGA-B6-A0RG, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 26.9 years (9,840 days).
Specimen TCGA-B6-A0RG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2393d723-dd70-4b7b-8ba9-a6cf4902c172.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0RG-10A (Blood Derived Normal), aliquot TCGA-B6-A0RG-10A-01W-A071-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27fd7d8a-9716-451b-bb23-32707470ef7b

The open-access MAF lists 63 somatic variants for this specimen: 54 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 47, Silent 9, Frame Shift Del 5, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 99/308 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSL4 | c.833C>G p.T278S (on ENST00000340800 / NM_022977.2; = p.T237S on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61615861; called by muse, mutect2, varscan2
- ADCY8 | c.3298G>A p.V1100I | Missense Mutation (SNP) | VAF 102/309 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751510726, COSV53920343; called by muse, mutect2, varscan2
- ARHGAP12 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1288547080, COSV60966306; called by muse, mutect2, varscan2
- ARID1A | c.6109C>T p.Q2037* | Nonsense Mutation (SNP) | VAF 88/203 reads (43%) | catalogued as COSV61372657; called by muse, mutect2, varscan2
- B3GAT3 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868665260, COSV53882542; called by muse, mutect2, varscan2
- CA5B | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 6/185 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100590827; called by muse, mutect2
- CAMK2D | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as COSV56439045; called by muse, mutect2, varscan2
- CFTR | c.1390A>T p.K464* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV50100246; called by muse, mutect2, varscan2
- CUL9 | c.4154C>G p.S1385C | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV52724736; called by muse, mutect2, varscan2
- DNAH8 | c.1711G>C p.A571P | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs756762480, COSV100547270; called by muse, mutect2
- DNMT3B | c.2240T>C p.I747T | Missense Mutation (SNP) | VAF 92/209 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.159); catalogued as COSV52423371; called by muse, mutect2, varscan2
- EFTUD2 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV101274561; called by muse, mutect2
- EMC8 | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53668581; called by muse, mutect2, varscan2
- ERBB4 | c.2108C>A p.T703K | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.086); catalogued as rs568046921, COSV53587099; called by muse, mutect2, varscan2
- FKBP8 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV55894103; called by muse, mutect2, varscan2
- FUT3 | c.943C>A p.R315S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as COSV54608549; called by muse, mutect2, varscan2
- HDX | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 29/409 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV99948077; called by muse, mutect2
- HECTD1 | c.4696C>G p.L1566V | Missense Mutation (SNP) | VAF 63/148 reads (43%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.931); catalogued as COSV67949148; called by muse, mutect2, varscan2
- KLHL20 | c.1111G>C p.G371R | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99268678; called by muse, mutect2
- KLHL41 | c.1762G>T p.A588S | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.852); catalogued as COSV99500628; called by muse, mutect2, varscan2
- MAP2K4 | c.783_784del p.D263Cfs*4 | Frame Shift Del (DEL) | VAF 87/135 reads (64%) | catalogued as COSV62256622; called by mutect2, pindel, varscan2
- MARCKSL1 | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61482432; called by muse, mutect2, varscan2
- MKS1 | c.1093A>G p.M365V | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs750926734, COSV99836786; called by muse, mutect2, varscan2
- MYO6 | c.1720G>C p.D574H | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs761375780, COSV64119228, COSV64121398; called by muse, mutect2, varscan2
- NEB | c.17239A>G p.K5747E | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51459795; called by muse, mutect2, varscan2
- PARP4 | c.3061G>T p.A1021S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV67964201; called by muse, mutect2, varscan2
- PARP4 | c.2158A>T p.N720Y | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67964205; called by muse, mutect2, varscan2
- PDE1A | c.1355C>T p.T452I | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs553030991, COSV59536418; called by muse, mutect2, varscan2
- PIAS2 | c.1805G>C p.S602T | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.015); catalogued as COSV67094930; called by muse, mutect2, varscan2
- PLEKHG4B | c.2465G>A p.R822Q (on ENST00000283426; = p.R1178Q on NM_052909.5) | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs146749875; called by muse, mutect2, varscan2
- POU6F2 | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV68870354, COSV68882556; called by muse, mutect2, varscan2
- PPT2 | c.714C>G p.F238L | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV61354851; called by muse, mutect2, varscan2
- PTPRD | c.4817A>C p.H1606P | Missense Mutation (SNP) | VAF 261/508 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61981346; called by muse, mutect2, varscan2
- PZP | c.3570G>C p.E1190D | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV54370422; called by muse, mutect2, varscan2
- RAG1 | c.1016A>T p.D339V | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV55028220; called by muse, mutect2, varscan2
- SHOC2 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99510516; called by muse, mutect2
- SLITRK2 | c.614T>C p.I205T | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV100158240; called by muse, mutect2
- TAF2 | c.1743T>G p.I581M | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100978817; called by muse, mutect2
- TARBP1 | c.2942G>C p.S981T | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV99241802, COSV99242124; called by muse, mutect2, varscan2
- TNRC6A | c.5299C>T p.P1767S | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.158); catalogued as COSV59370163; called by muse, mutect2, varscan2
- TRIM21 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.417); catalogued as rs768080889, COSV54342738; called by muse, mutect2
- TSSK2 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs772763295, COSV52818853; called by muse, mutect2, varscan2
- TUT7 | c.2301G>C p.Q767H | Missense Mutation (SNP) | VAF 135/285 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV52898920; called by muse, mutect2, varscan2
- UTP20 | c.5194A>G p.S1732G | Missense Mutation (SNP) | VAF 83/185 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV55385306; called by muse, mutect2, varscan2
- VANGL2 | c.1014C>G p.H338Q | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63605484; called by muse, mutect2, varscan2
- ZFHX3 | c.4532G>T p.G1511V | Missense Mutation (SNP) | VAF 116/144 reads (81%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.689); catalogued as COSV51735653; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1622A>G p.H541R | Missense Mutation (SNP) | VAF 12/370 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99837778; called by muse, mutect2
- ZNF347 | c.794G>C p.G265A | Missense Mutation (SNP) | VAF 90/420 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV61970929; called by muse, mutect2, varscan2
- BCDIN3D | c.88_104del p.P30Sfs*26 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel, varscan2
- GATA3 | c.1002_1003del p.D335Pfs*16 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- MARF1 | c.1169_1172del p.F390Sfs*17 | Frame Shift Del (DEL) | VAF 69/165 reads (42%) | called by mutect2, pindel, varscan2
- NRK | c.4275_4297del p.F1426Sfs*8 | Frame Shift Del (DEL) | VAF 21/87 reads (24%) | called by mutect2, pindel, varscan2
- TINAGL1 | c.1209G>C p.K403N | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- ATR | c.4809A>G p.K1603= | Silent (SNP) | VAF 35/226 reads (15%) | catalogued as rs777880900, COSV63392292; called by muse, mutect2, varscan2
- CHD9 | c.4893G>A p.V1631= | Silent (SNP) | VAF 31/36 reads (86%) | catalogued as COSV54616385; called by muse, mutect2, varscan2
- CUBN | c.6096T>C p.C2032= | Silent (SNP) | VAF 86/174 reads (49%) | catalogued as COSV64727151; called by muse, mutect2, varscan2
- CYSLTR2 | c.93C>T p.C31= | Silent (SNP) | VAF 139/155 reads (90%) | catalogued as COSV56166989; called by muse, mutect2, varscan2
- DGKG | c.333T>C p.D111= | Silent (SNP) | VAF 25/244 reads (10%) | catalogued as COSV53972713; called by muse, mutect2, varscan2
- HOXB3 | c.954G>A p.P318= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1245361808, COSV57486434; called by muse, mutect2, varscan2
- PLCH1 | c.2725C>A p.R909= (on ENST00000340059 / NM_001130960.2; = p.R901= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/121 reads (64%) | catalogued as rs748307014, COSV58210181; called by muse, mutect2, varscan2
- RNF113A | c.384C>T p.R128= | Silent (SNP) | VAF 117/492 reads (24%) | catalogued as COSV65097587; called by muse, mutect2, varscan2
- SP140 | c.717C>G p.P239= | Silent (SNP) | VAF 71/194 reads (37%) | catalogued as COSV100614108; called by muse, mutect2, varscan2
